Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9V2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9V2-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS 8070/3
Site: Cervix NOS C53.9
JN 3/7/14

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of cervix":

Moderately differentiated squamous cell carcinoma, invasive.
Vascular invasion absent in this sample.

Source: NCI Genomic Data Commons file 943e8ecb-15fc-418d-85f1-eccb479b68cb (TCGA-VS-A9V2.0D5FE178-46D8-41A5-BA54-E9746F3D2B4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).